Somatic mutation profile of tumor specimen MP2PRT-PAVECU-TMP1-A (aliquot MP2PRT-PAVECU-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVECU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (894 days).
Specimen MP2PRT-PAVECU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5a18e98-a13b-44f8-a9b4-0a8db6f09e91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVECU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVECU-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/988264eb-b22f-4574-a4cd-9eb64b7470d3

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF23 | c.2417G>A p.R806H (on ENST00000260363; = p.R702H on NM_004856.7) | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs763116733, COSV52981267; called by muse, mutect2, varscan2
- KRAS | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 37/451 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55502236; called by muse, mutect2
- PDE3B | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 39/405 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs748242339, COSV56385184; called by muse, mutect2
- SMIM17 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.083); catalogued as rs1409619816; called by muse, mutect2
- COLEC10 | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-8 | c.351delinsCTC p.*118Sfs*? | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by pindel, varscan2*
- NPFFR1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 24/724 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2
- PAPPA2 | c.3359T>C p.V1120A | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- IGKV1D-8 | chr2:90221384 CCACAGTGTTACACACCCGAAC>TCCACCGACACAGGGGAACCGCGACTTA | Silent (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2*
- MALRD1 | c.4566T>A p.T1522= | Silent (SNP) | VAF 117/360 reads (33%) | called by muse, mutect2, varscan2
